Surgical pathology report (de-identified scan), TCGA case TCGA-DQ-7592, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Of Michigan, specimen TCGA-DQ-7592-01A (Primary Tumor).

[page 1 of 4]
HISTORY:

History of oral tongue squamous cell carcinoma. Operative Procedure/Tissue Submitted: Glossectomy [REDACTED].

GROSS:

1. "Right level II, external jugular lymph node" A 0.8 cm tan lymph node.
1A. Frozen section control. (Ins, fat retained)
2. "Submental deep anterior margin" A 0.8 x 0.5 x 0.3 cm red tissue bit.
Frozen section control. [REDACTED]
3. "Right lingual nerve posterior margin" A 0.5 x 0.3 x 0.3 cm tan soft tissue fragment.
Frozen section control. [REDACTED]
4. "Left lingual nerve posterior margin" A 0.4 x 0.3 x 0.2 cm red-tan tissue bit.
Frozen section control. [REDACTED]
5. "Posterior margin left styloglossus" A 0.8 x 0.5 x 0.3 cm red soft tissue bit.
Frozen section control. [REDACTED]
6. "Posterior margin left palatoglossus" A 0.8 x 0.3 x 0.3 cm red soft tissue bit.
Frozen section control. [REDACTED]
7. "Posterior margin midline tongue" A 1.0 x 0.6 x 0.5 cm, red-tan tissue bit.
Frozen section control. [REDACTED]
8. "Left hypoglossus posterior margin" A 0.3 x 0.2 x 0.3 cm, red-tan bit.
~~Frozen section control. [REDACTED]~~
9. "Right dorsal tongue posterior margin" A 0.7 x 0.4 x 0.3 cm red tissue bit.
Frozen section control. [REDACTED]
10. "Right base of tongue posterior margin" A 1.4 x 0.3 x 0.3 cm red tissue bit.
Frozen section control. [REDACTED]
11. "Subtotal glossectomy." Received in formalin in a large container is a 10.6 x 6.7 x 4.3 cm, subtotal glossectomy with bilateral attached submandibular glands. The attached soft tissue with submandibular gland measures 14 x 4 x 1.5 cm. A portion of the right posterior base of tongue has been resected. The anterior floor of mouth and lateral gingiva are present. The left lateral tongue and lateral floor of mouth with extension to the anterior floor of mouth is remarkable for an ulcerative, gray-tan tumor, 6.7 x 3.2 cm. It is 0.5 cm away from the posterior left base of tongue 1.3 cm from the lateral gingival mucosal margin and 0.5 cm away from the left anterior floor of mouth. Punctate hemorrhages with possible tumor nodules extending from the lateral tumor are noted to have been previously incised. The inferior base margin of resection is inked green. The right lateral margin of resection is inked blue. The left lateral resection is inked black. Anterior floor of mouth yellow. Tumor has a maximum depth of 2.9 cm. It is 0.3 cm away from the inferior soft tissue margin. It is 1.1 cm away from the right lateral margin of resection. The right submandibular gland is 4.2 x 3.6 x 2.2 cm. The cut surface is unremarkable. Multiple lymph nodes are identified ranging up to 1.5 cm. The left submandibular gland is 5.5 x 2.2 x 2.3 cm. Multiple possible lymph nodes are identified ranging up to 2.2 cm. 11A. Anterior floor of mouth with sublingual gland and tumor. [REDACTED]
11B. Tumor of lateral tongue to lateral gingiva. [REDACTED]
11C. Left inferior base of tongue with tumor. [REDACTED]
11D. Tumor to right lateral margin. [REDACTED]

[page 2 of 4]
11E. Tumor to posterior left base of tongue. [REDACTED]
11F. Tumor to dorsal tongue. [REDACTED]
11G. Right submandibular gland. [REDACTED]
11H. Multiple level I lymph nodes. [REDACTED]
11I-J. Largest level I lymph node. [REDACTED]
11K. Left submandibular gland. [REDACTED]
11L. Multiple level I lymph nodes. [REDACTED]
11M-N. One bisected left level I lymph node each. [REDACTED]
11O. Largest level I lymph node sectioned, left. [REDACTED]
Photographs have been taken.
12. "Left neck level I." Received in formalin in a small container is a 4.6 x 4.1 x 3.2 cm irregular portion of yellow fibroadipose tissue. Three possible lymph nodes are identified ranging up to 0.3 cm.
12A. Level I lymph node. [REDACTED]
13. "Left neck level II." Received in formalin in a small container is a 5.5 x 4.2 x 1.3 cm, irregular portion of yellow, fibroadipose tissue. Also possible lymph nodes are identified ranging up to 2.5 cm. The largest lymph node is remarkable for a gray-white possible portion of tumor.
13A. Multiple possible lymph nodes. [REDACTED]
13B-F. One bisected lymph node each. [REDACTED]
13G. Largest lymph node. [REDACTED]
14. "Left neck level III." Received in formalin in a small container is a 4.2 x 3.9 x 1.3 cm, irregular portion of fibroadipose tissue. Fibromuscular tissue is present. Multiple possible lymph nodes are identified ranging up to 2.1 cm. The largest has a gray-white cut surface.
14A. Two possible lymphs. [REDACTED]
14B-C. One bisected lymph node each. [REDACTED]
14D. Largest lymph node. [REDACTED]
15. "Left neck level IV." Received in formalin in a small container is a 4.3 x 3.6 x 1.3 cm, irregular portion of yellow fibroadipose tissue. Multiple possible lymph nodes are identified ranging up to 1.3 cm.
15A. Multiple possible lymph nodes. [REDACTED]
15B-C. One bisected lymph node each. [REDACTED]
[REDACTED]

FROZEN SECTION REPORT

1&2. Negative for carcinoma [REDACTED]
3. Negative for carcinoma. [REDACTED]
4-8. Negative for cancer. [REDACTED]
9&10. Negative for carcinoma [REDACTED]

I, [REDACTED], M.D., have reviewed and interpreted the frozen section material at the time it was requested.

I, [REDACTED], M.D., have reviewed and interpreted the frozen section material at the time it was requested.

Permanent sections confirm frozen section report.

MICROSCOPIC:

SQUAMOUS LESIONS OF HEAD & NECK: RESECTION

Site: Tongue

Findings: Squamous cell carcinoma

Differentiation: Moderate

Gross: Ulcerative Size 6.7 cm (largest dimension)

[page 3 of 4]
Invasion: Present If present: depth 2.9 cm.

Tumor border: Infiltrative

Perineural invasion: Present If present: Extensive

Vascular invasion: Absent

Bone/Cartilage invasion: N/A

Lymphocyte infiltration: Absent

Margins: Negative

SQUAMOUS LESIONS OF HEAD & NECK: LYMPH NODE DISSECTIONS

RIGHT

LEVEL (or site)	#Positive	#Negative	Extracapsular extension
--------------------	-----------	-----------	----------------------------

I	0	7	N/A
---	---	---	-----

II	0	1	N/A
----	---	---	-----

TOTAL	0	8	N/A
-------	---	---	-----

LEFT

LEVEL (or site)	#Positive	#Negative	Extracapsular extension
--------------------	-----------	-----------	----------------------------

I	0	7	N/A
---	---	---	-----

II	2	10	Present
----	---	----	---------

III	1	4	Absent
-----	---	---	--------

IV	0	10	N/A
----	---	----	-----

TOTAL	3	31	Present
-------	---	----	---------

[page 4 of 4]
MICROSCOPIC DIAGNOSIS:

1. External jugular lymph node, right level II, resection: One lymph node, negative for carcinoma.

2-11. Tongue, subtotal glossectomy and separately submitted margins: Moderately-differentiated squamous cell carcinoma (6.7 cm) involving left tongue, invading to a depth of 2.9 cm. Extensive perineural invasion identified. Margins negative. See TEMPLATE. Unremarkable submandibular glands. Fourteen lymph nodes negative for carcinoma (0/14).

12. Soft tissue of left neck, level I, dissection: Fibroadipose tissue, negative for neoplasm. No lymphoid tissue present.

13. Soft tissue of left neck, level II, dissection: Metastatic squamous cell carcinoma involving two of twelve lymph nodes (2/12) with extracapsular extension.

14. Soft tissue of left neck, level III, dissection: Metastatic squamous cell carcinoma involving one of five lymph nodes (1/5).

15. Soft tissue of left neck, level IV, dissection: Ten lymph nodes negative for carcinoma (0/10).

I, [REDACTED] M.D., the signing staff pathologist, have personally examined and interpreted the slides from this case.

Close

Source: NCI Genomic Data Commons file 1e8ea939-9d33-4972-b09c-53ac316c8243 (TCGA-DQ-7592.27D979BC-E229-44A0-94FB-599D58C6F5D6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).